Somatic mutation profile of tumor specimen TCGA-B8-5165-01A (aliquot TCGA-B8-5165-01A-01D-1421-08) from TCGA case TCGA-B8-5165, project TCGA-KIRC (Kidney Renal Clear Cell Carcinoma). Sex at birth: male; Vital status: Alive; Primary diagnosis: Clear cell adenocarcinoma, NOS; Tissue or organ of origin: Kidney, NOS; AJCC pathologic stage: Stage I; Tumor grade: G2; Age at diagnosis: 43.5 years (15,898 days).
Specimen TCGA-B8-5165-01A: Sample type: Primary Tumor; Tissue type: Tumor; Tumor descriptor: Primary.
Source: NCI Genomic Data Commons open-access Masked Somatic Mutation file (Mutation Annotation Format, MAF) ba5c71e2-a55b-4f13-ab8b-0ab48e06baee.wxs.aliquot_ensemble_masked.maf.gz, workflow Aliquot Ensemble Somatic Variant Merging and Masking; Data Release 46.0 - August 10, 2026. Variants were called in the tumor against matched normal specimen TCGA-B8-5165-10A (Blood Derived Normal), aliquot TCGA-B8-5165-10A-01D-1421-08; read counts below are tumor reads.
https://portal.gdc.cancer.gov/files/e691ebaf-6cf1-4787-90b5-08dc351d348e

The open-access MAF lists 22 somatic variants for this specimen: 15 protein-altering or splice-affecting, 6 silent, 1 other (UTR, intronic, flanking, RNA and similar).
By variant classification: Missense Mutation 11, Silent 6, Nonsense Mutation 2, Splice Site 1, 3'UTR 1, Frame Shift Ins 1.

Variants (all; order: hotspot or ClinVar-pathogenic variants first, then other protein-altering variants with a dbSNP/COSMIC/ClinVar record ('catalogued as' / 'ClinVar'), then the remaining protein-altering, then silent, then non-coding — alphabetical by gene within each group; each line: gene | DNA and protein change | classification | tumor variant allele fraction (VAF) | annotations). Protein positions are numbered on GDC's canonical Ensembl transcript (GENCODE v36); where an older RefSeq transcript numbers the protein differently, the line names both transcripts and gives that numbering too:
- VHL | c.463+1G>T p.X155_splice | Splice Site (SNP) | VAF 29/176 reads (16%) | hotspot (GDC flag); catalogued as CS004297, CS111451, CS961708, COSV56543633, COSV56544194, COSV56546569, COSV56552736; called by muse, mutect2, varscan2
- C3orf62 | c.121T>C p.C41R | Missense Mutation (SNP) | VAF 16/66 reads (24%) | SIFT deleterious (0); PolyPhen probably damaging (0.996); catalogued as COSV55540396; called by muse, mutect2, varscan2
- CDH18 | c.1805C>G p.A602G | Missense Mutation (SNP) | VAF 8/44 reads (18%) | SIFT tolerated (0.1); PolyPhen benign (0.029); catalogued as COSV56935266, COSV56958927; called by muse, mutect2, varscan2
- ERBB3 | c.3799C>T p.R1267* | Nonsense Mutation (SNP) | VAF 21/132 reads (16%) | catalogued as rs745487835, COSV57262894; called by muse, mutect2, varscan2
- KRT84 | c.1339G>C p.E447Q | Missense Mutation (SNP) | VAF 6/57 reads (11%) | SIFT deleterious (0.02); PolyPhen possibly damaging (0.835); catalogued as COSV57773058, COSV57773641; called by muse, mutect2, varscan2
- LGR6 | c.2158T>G p.Y720D (on ENST00000367278 / NM_001017403.1; = p.Y668D on NM_021636.3) | Missense Mutation (SNP) | VAF 6/39 reads (15%) | SIFT tolerated (0.08); PolyPhen possibly damaging (0.648); catalogued as COSV55165844; called by muse, mutect2, varscan2
- LRRC37B | c.163C>T p.L55F | Missense Mutation (SNP) | VAF 27/170 reads (16%) | SIFT tolerated (0.05); PolyPhen benign (0.028); catalogued as COSV58954802; called by muse, mutect2, varscan2
- PCDHGB3 | c.1847T>A p.L616Q | Missense Mutation (SNP) | VAF 28/99 reads (28%) | SIFT deleterious (0); PolyPhen probably damaging (0.999); catalogued as COSV54027023; called by muse, mutect2, varscan2
- PLCH1 | c.4042C>T p.P1348S (on ENST00000340059 / NM_001130960.2; = p.P1340S on NM_014996.4 and 1 other RefSeq transcript) | Missense Mutation (SNP) | VAF 6/101 reads (6%) | SIFT deleterious, low confidence (0.02); PolyPhen benign (0.001); catalogued as COSV58203236; called by muse, mutect2
- RIPK1 | c.1994T>A p.L665* | Nonsense Mutation (SNP) | VAF 9/36 reads (25%) | catalogued as COSV52531624; called by muse, mutect2, varscan2
- RLF | c.1336C>T p.P446S | Missense Mutation (SNP) | VAF 17/303 reads (6%) | SIFT deleterious (0.05); PolyPhen benign (0); catalogued as COSV65653136; called by muse, mutect2
- SAR1B | c.188A>T p.E63V | Missense Mutation (SNP) | VAF 58/285 reads (20%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.936); catalogued as COSV68392035; called by muse, mutect2, varscan2
- SLC37A4 | c.730A>G p.T244A | Missense Mutation (SNP) | VAF 7/34 reads (21%) | SIFT tolerated (0.22); PolyPhen benign (0.005); catalogued as COSV58156247; called by muse, mutect2, varscan2
- TRHR | c.1031A>C p.K344T | Missense Mutation (SNP) | VAF 33/207 reads (16%) | SIFT tolerated (0.17); PolyPhen benign (0.108); catalogued as COSV61236360; called by muse, mutect2, varscan2
- ZNF512B | c.783dup p.K262Qfs*82 | Frame Shift Ins (INS) | VAF 81/532 reads (15%) | called by mutect2, pindel, varscan2
- DUSP14 | c.192T>C p.P64= | Silent (SNP) | VAF 31/108 reads (29%) | called by muse, mutect2, varscan2
- ITK | c.432C>T p.A144= | Silent (SNP) | VAF 11/160 reads (7%) | catalogued as COSV70065090; called by muse, mutect2
- NPAT | c.2841G>C p.G947= | Silent (SNP) | VAF 28/213 reads (13%) | catalogued as COSV53721633; called by muse, mutect2, varscan2
- SLC34A1 | c.1917C>A p.L639= | Silent (SNP) | VAF 26/101 reads (26%) | catalogued as COSV53693053; called by muse, mutect2, varscan2
- SLC38A1 | c.240A>G p.L80= | Silent (SNP) | VAF 11/44 reads (25%) | catalogued as rs1363040292, COSV67064877; called by muse, mutect2, varscan2
- SLC9A6 | c.486T>C p.Y162= | Silent (SNP) | VAF 39/111 reads (35%) | catalogued as COSV65788986; called by muse, mutect2, varscan2
- LRRC8A | c.*2C>T | 3'UTR (SNP) | VAF 7/27 reads (26%) | catalogued as rs774080181, COSV52190383; called by muse, mutect2, varscan2
